Somatic mutation profile of tumor specimen TCGA-ZF-AA4T-01A (aliquot TCGA-ZF-AA4T-01A-11D-A38G-08) from TCGA case TCGA-ZF-AA4T, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.6 years (23,974 days).
Specimen TCGA-ZF-AA4T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e97f3c7-758e-4b1f-92dc-6669adbb606e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4T-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4T-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef526a1a-f7f1-499a-94fd-0d4c2bdd0d7a

The open-access MAF lists 112 somatic variants for this specimen: 81 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 29, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3657C>A p.N1219K (on ENST00000404938 / NM_001163941.2; = p.N774K on NM_178559.6) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs200868952, COSV51708334, COSV99327326, COSV99328542; called by muse, mutect2, varscan2
- ADGRG5 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1352053499, COSV61083177; called by muse, mutect2, varscan2
- AGO3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs1342440409, COSV55793063; called by muse, mutect2, varscan2
- ALG13 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV52638179, COSV52639551; called by muse, mutect2, varscan2
- ANK3 | c.10153A>G p.N3385D | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV55055314; called by muse, mutect2, varscan2
- ARHGAP20 | c.753A>C p.E251D | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.255); catalogued as COSV52810129; called by muse, mutect2, varscan2
- ATXN7L2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.166); catalogued as COSV60204655; called by muse, mutect2, varscan2
- BDKRB2 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100020843; called by muse, mutect2
- BUB3 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64363654, COSV64363756; called by muse, mutect2, varscan2
- CASR | c.1217C>G p.T406S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.078); catalogued as COSV56136893; called by muse, mutect2, varscan2
- CDCA7L | c.999A>T p.L333F | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100176647; called by muse, mutect2
- CGB5 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.414); catalogued as COSV100031909; called by mutect2, varscan2
- CLTC | c.2792T>C p.I931T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs749634959, COSV52247147; called by muse, mutect2, varscan2
- CNTN6 | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63170303; called by muse, mutect2
- COL5A3 | c.4252G>A p.G1418S | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53409850; called by muse, mutect2, varscan2
- COL7A1 | c.8330G>A p.R2777Q | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs748439088, COSV56476367, COSV56476412; called by muse, mutect2, varscan2
- COX5A | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59279133; called by muse, mutect2, varscan2
- CYTH2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs1479118181, COSV57309216; called by muse, mutect2, varscan2
- CYTH2 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV57309236; called by muse, mutect2
- DAZL | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as rs1310143028, COSV51712618; called by muse, mutect2, varscan2
- DBT | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64497416; called by muse, mutect2, varscan2
- DCAF13 | c.711A>T p.L237F | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV52571565; called by muse, mutect2
- DGAT1 | c.1204A>T p.M402L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1205104526, COSV60047606; called by muse, mutect2, varscan2
- DOK2 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99374517; called by muse, mutect2
- EDEM2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65712911; called by muse, mutect2, varscan2
- ELF3 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100668618, COSV62839941; called by muse, mutect2
- FAM124A | c.493G>A p.V165M (on ENST00000322475 / NM_001242312.2; = p.V201M on NM_145019.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1261171304, COSV54476020; called by muse, mutect2, varscan2
- FETUB | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs754587475, COSV54005413; called by muse, mutect2, varscan2
- GLRA1 | c.1267A>C p.I423L (on ENST00000455880 / NM_001146040.2; = p.I415L on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51011496; called by muse, mutect2, varscan2
- GPX5 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs775350924, COSV69079325; called by muse, mutect2, varscan2
- GRM4 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs764896879, COSV65212790; called by muse, mutect2, varscan2
- H3C7 | c.11C>G p.T4R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99769007; called by muse, mutect2
- HECTD3 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV55799977, COSV99869824; called by muse, mutect2, varscan2
- HNRNPF | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV100563074, COSV61560909; called by muse, mutect2
- ITGB3 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs774343946, COSV71383917; called by muse, mutect2
- KANK2 | c.2483G>A p.R828H (on ENST00000586659 / NM_001379562.1; = p.R836H on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200363050, COSV62007688; called by muse, mutect2, varscan2
- KLHL28 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV61888001; called by muse, mutect2, varscan2
- LRIF1 | c.974A>G p.K325R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV63897192; called by muse, mutect2, varscan2
- LTF | c.1589A>T p.E530V | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV51607528; called by muse, mutect2
- MAP2K3 | c.455G>A p.R152Q (on ENST00000342679 / NM_145109.3; = p.R123Q on NM_002756.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs148304866; called by mutect2, varscan2
- MKX | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65392032; called by muse, mutect2, varscan2
- MOB3C | c.370T>A p.W124R | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596162; called by muse, mutect2
- MORC1 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV51718743, COSV51729005; called by muse, mutect2, varscan2
- MUC16 | c.12356C>A p.T4119K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs1262333777, COSV67462000; called by muse, mutect2
- NAALADL1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV60523707; called by muse, mutect2, varscan2
- NADSYN1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs762179995, COSV59811757; called by muse, mutect2, varscan2
- NEB | c.4016C>T p.S1339L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV51158311; called by muse, mutect2, varscan2
- NMRK1 | c.7A>C p.T3P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV63112163; called by muse, mutect2, varscan2
- NOM1 | c.1870A>G p.N624D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs762400061, COSV51979823; called by muse, mutect2, varscan2
- OR6N1 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100625140, COSV58648132; called by muse, mutect2, varscan2
- PDIK1L | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV65322524; called by muse, mutect2
- PLSCR2 | c.563G>T p.G188V (on ENST00000497985 / NM_001199978.1; = p.G115V on NM_020359.2) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100367588; called by muse, mutect2
- PNLIPRP1 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100724231; called by muse, mutect2
- PPM1G | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 40/181 reads (22%) | catalogued as rs375191761; called by muse, mutect2, varscan2
- PRRG4 | c.122A>C p.E41A | Missense Mutation (SNP) | VAF 125/169 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1224888762, COSV57672966; called by muse, mutect2, varscan2
- PTK2 | c.2580A>G p.I860M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs1443013932, COSV61785041; called by muse, mutect2, varscan2
- RBM28 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.635); catalogued as COSV56162088; called by muse, mutect2, varscan2
- RSPO2 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752947067, COSV52643151, COSV52652876; called by muse, mutect2
- RTP1 | c.161T>A p.M54K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs781060697, COSV56618291; called by muse, mutect2, varscan2
- SCARA5 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61571869; called by mutect2, varscan2
- SCARA5 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61571875; called by mutect2, varscan2
- SETBP1 | c.2507C>A p.A836D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56320089; called by muse, mutect2, varscan2
- SLC25A23 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs367895517; called by muse, mutect2, varscan2
- STK32B | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); catalogued as COSV51483699; called by muse, mutect2
- SV2A | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64964603; called by muse, mutect2, varscan2
- SYNE2 | c.18538G>A p.E6180K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV59948641; called by muse, mutect2, varscan2
- TM9SF2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64506667; called by muse, mutect2, varscan2
- VRK2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs1228024879, COSV60876261; called by muse, mutect2, varscan2
- WTIP | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54328076; called by muse, mutect2, varscan2
- ZNF276 | c.1342G>A p.A448T (on ENST00000443381 / NM_001113525.2; = p.A373T on NM_152287.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs576654600, COSV57067701, COSV57070084; called by muse, mutect2, varscan2
- ZNF317 | c.1624G>C p.G542R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV56109396, COSV56109484; called by muse, mutect2, varscan2
- ZNF354C | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59608079; called by muse, mutect2, varscan2
- ZNF366 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV59215162; called by muse, mutect2, varscan2
- ZNF516 | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71586950; called by muse, mutect2, varscan2
- ARRDC5 | c.879_891delinsG p.Y293_T297delins* (on ENST00000381781; = p.Y279_T283delins* on NM_001080523.3 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 44/85 reads (52%) | called by pindel, varscan2*
- DHDDS | c.907_908del p.S303Gfs*20 (on ENST00000236342 / NM_001319959.1; = p.S304Gfs*20 on NM_024887.3) | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- DMXL2 | c.4367dup p.Y1456* | Nonsense Mutation (INS) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- KAT7 | c.1112_1115dup p.K373Ffs*25 | Frame Shift Ins (INS) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- POF1B | c.171dup p.P58Afs*61 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- RB1 | c.1468_1469dup p.E492Lfs*4 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.1410C>T p.T470= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV55779973; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1764C>T p.Y588= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs986247139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ART4 | c.918C>T p.V306= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV57451745; called by muse, mutect2, varscan2
- ATAD2B | c.1714C>T p.L572= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV53197207, COSV99476875; called by muse, mutect2
- CENPF | c.9270C>T p.V3090= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs533012183, COSV65274484; called by muse, mutect2, varscan2
- CHERP | c.1806G>A p.P602= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs557288720, COSV52223067; called by muse, mutect2, varscan2
- DNMT1 | c.2151A>G p.K717= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV61578833; called by muse, mutect2, varscan2
- FMNL2 | c.2271G>A p.K757= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV56493940; called by muse, mutect2, varscan2
- IFNE | c.378G>A p.L126= | Silent (SNP) | VAF 21/223 reads (9%) | catalogued as rs1309827228, COSV58640452; called by muse, mutect2
- IL22RA1 | c.267G>A p.T89= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs142566825; called by muse, mutect2, varscan2
- ISM2 | c.1413G>A p.T471= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs371716934, COSV99376702; called by muse, mutect2, varscan2
- ITIH6 | c.1653G>A p.E551= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99512783; called by muse, mutect2
- MOB3C | c.171C>T p.D57= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54719043; called by muse, mutect2, varscan2
- NAALADL1 | c.417G>T p.G139= | Silent (SNP) | VAF 53/96 reads (55%) | catalogued as COSV60523697; called by muse, mutect2, varscan2
- NKG7 | c.399C>T p.F133= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV52467423, COSV99389994; called by muse, mutect2, varscan2
- OR1S1 | c.663C>T p.I221= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as COSV58706912; called by muse, mutect2, varscan2
- OR4C13 | c.432A>G p.G144= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1555015790, COSV73648727; called by muse, mutect2, varscan2
- OR5B2 | c.312C>G p.A104= | Silent (SNP) | VAF 48/79 reads (61%) | catalogued as COSV56908101; called by muse, mutect2, varscan2
- OR5T1 | c.837T>G p.T279= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs1202560100, COSV57302542, COSV57304590; called by muse, mutect2
- OR6N1 | c.687C>A p.P229= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV58648119; called by muse, mutect2, varscan2
- SERPINA3 | c.864A>G p.E288= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV101261795, COSV67585994; called by muse, mutect2, varscan2
- SERPINB4 | c.420A>G p.P140= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV61984812; called by muse, mutect2, varscan2
- SETBP1 | c.2508C>A p.A836= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV56320096; called by muse, mutect2, varscan2
- SLC12A9 | c.789C>T p.A263= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs140425277; called by muse, mutect2, varscan2
- SLC25A6 | c.672C>T p.A224= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs143974718, COSV58430952; called by muse, mutect2, varscan2
- TF | c.141C>T p.S47= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs929317541, COSV53919863; called by muse, mutect2, varscan2
- TLR4 | c.726A>G p.V242= (on ENST00000355622 / NM_138554.5; = p.V202= on NM_003266.4) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs199501625, COSV62923110; called by muse, mutect2, varscan2
- ZNF366 | c.498C>G p.P166= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV59215151; called by muse, mutect2, varscan2
- ZNF516 | c.2223G>T p.R741= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV71586949; called by muse, varscan2
- DUSP4 | c.433+4419G>T | Intron (SNP) | VAF 13/42 reads (31%) | catalogued as COSV53545614; called by muse, mutect2, varscan2
- RBM15 | c.*84C>G | 3'UTR (SNP) | VAF 33/172 reads (19%) | catalogued as COSV100873387; called by muse, varscan2
